Gene-level copy-number profile of tumor specimen TCGA-ZG-A8QY-01A from TCGA case TCGA-ZG-A8QY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.7 years (24,731 days).
Specimen TCGA-ZG-A8QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.2c5d7d19-0868-4f01-87ed-cca5556a2995.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A8QY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4dd324e8-2b7c-4f9b-98d6-1e6fbadf5407

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 7,546; copy number 2: 51,732; copy number 3: 460.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A8QY-01A-11D-A376-01): tumor purity 0.55, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,406,752–134,725,474, 24 genes: RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93, AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2.
- chr5:98,853,985–99,595,297, 11 genes (within-gene range 0–1): CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2.
- chr6:95,504,182–95,632,929, 4 genes: CYCSP17, MANEA-DT, MANEA, AL607077.1.
- chr6:96,648,489–97,140,754, 10 genes (within-gene range 0–1): RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32.
- chr6:97,710,953–97,717,197, 1 gene (within-gene range 0–1): AL080316.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
